Somatic mutation profile of tumor specimen TCGA-B8-5553-01A (aliquot TCGA-B8-5553-01A-01D-1534-10) from TCGA case TCGA-B8-5553, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 67.7 years (24,729 days).
Specimen TCGA-B8-5553-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ece4fbd-d65f-4bcd-9c4d-084517f38757.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-5553-10A (Blood Derived Normal), aliquot TCGA-B8-5553-10A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e50937cd-2760-4ef8-8347-7781b5125b5b

The open-access MAF lists 53 somatic variants for this specimen: 42 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 10, Nonsense Mutation 6, Frame Shift Del 4, Splice Site 3, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAR | c.956C>A p.A319D | Missense Mutation (SNP) | VAF 47/190 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52720268; called by muse, mutect2, varscan2
- AGK | c.1226A>G p.D409G | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as rs1562988760, COSV62595811; called by muse, mutect2, varscan2
- AMN1 | c.510G>C p.Q170H | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV55672930; called by muse, mutect2, varscan2
- ATP11B | c.3296C>G p.P1099R | Missense Mutation (SNP) | VAF 61/386 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as COSV60032935; called by muse, mutect2, varscan2
- BICC1 | c.1261G>T p.G421W | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54066407; called by muse, mutect2, varscan2
- CANT1 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | catalogued as COSV56606626; called by muse, mutect2, varscan2
- CEMIP2 | c.3197A>G p.N1066S | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs747852965, COSV65485046; called by muse, mutect2, varscan2
- COL16A1 | c.3019-2A>T p.X1007_splice | Splice Site (SNP) | VAF 12/52 reads (23%) | catalogued as COSV54712960; called by muse, mutect2, varscan2
- ERBB4 | c.2716T>A p.Y906N | Missense Mutation (SNP) | VAF 38/619 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV100726882; called by muse, mutect2
- FLG | c.120A>T p.E40D | Missense Mutation (SNP) | VAF 153/764 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64247785; called by muse, mutect2, varscan2
- FXYD1 | c.163G>T p.V55L | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.132); catalogued as COSV54343948; called by muse, mutect2, varscan2
- GABPB1 | c.276+1G>T p.X92_splice | Splice Site (SNP) | VAF 66/298 reads (22%) | catalogued as COSV55017312; called by muse, mutect2, varscan2
- HERC1 | c.12027G>C p.Q4009H | Missense Mutation (SNP) | VAF 76/404 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV71249934; called by muse, mutect2, varscan2
- IPO5 | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV55159167; called by muse, mutect2, varscan2
- KBTBD4 | c.326A>C p.K109T | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); catalogued as COSV55456189; called by muse, mutect2, varscan2
- KDM4B | c.1919T>A p.F640Y | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.04); catalogued as COSV99347176; called by muse, mutect2
- KLF3 | c.977A>G p.D326G | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV54712408; called by muse, mutect2, varscan2
- LY96 | c.47C>G p.T16S | Missense Mutation (SNP) | VAF 162/739 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.398); catalogued as COSV53026621; called by muse, mutect2, varscan2
- MAP3K4 | c.3270G>T p.R1090S | Missense Mutation (SNP) | VAF 179/847 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100815624; called by muse, mutect2, varscan2
- MYH7B | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 6/49 reads (12%) | catalogued as COSV53424777; called by muse, mutect2, varscan2
- NHS | c.3205G>C p.D1069H | Missense Mutation (SNP) | VAF 159/818 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66281617; called by muse, mutect2, varscan2
- NLGN1 | c.1246T>C p.S416P | Missense Mutation (SNP) | VAF 19/559 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV100849924; called by muse, mutect2
- OR4K5 | c.358T>C p.Y120H | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV60005072; called by muse, mutect2, varscan2
- PLAG1 | c.300G>A p.M100I | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.287); catalogued as COSV57614481; called by muse, mutect2, varscan2
- PLEKHA7 | c.3122del p.G1041Vfs*31 | Frame Shift Del (DEL) | VAF 17/134 reads (13%) | catalogued as rs1564909057, COSV60580861; called by mutect2, pindel, varscan2
- PLG | c.875C>G p.S292C | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV51986049; called by muse, mutect2, varscan2
- PYGM | c.1449G>T p.K483N | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51216378; called by muse, mutect2, varscan2
- RPL27 | c.256T>A p.S86T | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.257); catalogued as COSV53815380; called by muse, mutect2, varscan2
- SLC22A6 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV64560975; called by muse, mutect2, varscan2
- SLC22A8 | c.242A>G p.N81S | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as rs774027900, COSV60326842; called by muse, mutect2, varscan2
- SLC44A1 | c.1492C>T p.Q498* | Nonsense Mutation (SNP) | VAF 64/326 reads (20%) | catalogued as COSV58267091; called by muse, mutect2, varscan2
- TADA1 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 109/508 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV63310604; called by muse, mutect2, varscan2
- TRIM24 | c.3141G>C p.Q1047H (on ENST00000343526 / NM_015905.3; = p.Q1013H on NM_003852.4) | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV58977441; called by muse, mutect2
- UCP2 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 27/149 reads (18%) | catalogued as COSV60105230; called by muse, mutect2, varscan2
- VCAN | c.514T>G p.C172G | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54115219; called by muse, mutect2, varscan2
- ZNF415 | c.1321A>T p.K441* | Nonsense Mutation (SNP) | VAF 38/145 reads (26%) | catalogued as COSV54704525; called by muse, mutect2, varscan2
- DDX55 | c.1761_1762del p.K587Nfs*12 | Frame Shift Del (DEL) | VAF 61/304 reads (20%) | called by mutect2, pindel, varscan2
- LIMS1 | c.803dup p.N268Kfs*2 | Frame Shift Ins (INS) | VAF 63/452 reads (14%) | called by mutect2, pindel, varscan2
- PANK1 | c.1616_1619del p.I539Tfs*17 (on ENST00000307534 / NM_148977.2; = p.I255Tfs*17 on NM_138316.4) | Frame Shift Del (DEL) | VAF 33/184 reads (18%) | called by mutect2, pindel, varscan2
- PIAS2 | c.862-1_862del p.X288_splice | Splice Site (DEL) | VAF 84/446 reads (19%) | called by pindel, varscan2
- RPL7A | c.378_379del p.D127Rfs*14 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.859G>T p.G287* | Nonsense Mutation (SNP) | VAF 24/133 reads (18%) | called by muse, mutect2, varscan2
- ADORA3 | c.936C>T p.S312= | Silent (SNP) | VAF 26/172 reads (15%) | catalogued as rs1473275308, COSV53986770; called by muse, mutect2, varscan2
- BRWD3 | c.4017G>A p.E1339= | Silent (SNP) | VAF 64/282 reads (23%) | catalogued as COSV64752951; called by muse, mutect2, varscan2
- DENND5A | c.225T>C p.S75= | Silent (SNP) | VAF 124/584 reads (21%) | catalogued as COSV100065130; called by muse, varscan2
- FAM124A | c.1011T>G p.P337= (on ENST00000322475 / NM_001242312.2; = p.P373= on NM_145019.4) | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV99696428; called by muse, mutect2, varscan2
- MUC5B | c.10272C>A p.T3424= | Silent (SNP) | VAF 58/367 reads (16%) | catalogued as COSV101500665; called by muse, mutect2, varscan2
- MYO5C | c.4095A>G p.Q1365= | Silent (SNP) | VAF 25/233 reads (11%) | catalogued as rs1235725369, COSV55911471; called by muse, mutect2, varscan2
- PALB2 | c.252C>A p.I84= | Silent (SNP) | VAF 39/212 reads (18%) | catalogued as COSV55169728, COSV99848929; called by muse, mutect2, varscan2
- SCN10A | c.2949G>A p.E983= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as rs1479121016; called by muse, mutect2
- STRN | c.687C>T p.S229= | Silent (SNP) | VAF 70/362 reads (19%) | catalogued as rs548893424, COSV55751637; called by muse, mutect2, varscan2
- ZUP1 | c.1434T>C p.C478= | Silent (SNP) | VAF 19/436 reads (4%) | catalogued as rs1435376030, COSV100885136; called by muse, mutect2
- MYBBP1A | c.*471A>C | 3'UTR (SNP) | VAF 16/275 reads (6%) | catalogued as COSV99626778; called by muse, mutect2
